Gene-level copy-number profile of tumor specimen TCGA-AX-A06B-01A from TCGA case TCGA-AX-A06B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 72.1 years (26,348 days).
Specimen TCGA-AX-A06B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.eeed3e03-dc6e-4038-8a86-f17e42271798.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A06B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f61f57fb-1776-45dd-b228-630a229a2892

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 23,624; copy number 2: 30,793; copy number 3: 5,104; copy number 4: 147; copy number 5: 3; copy number 6: 23; copy number 8: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A06B-01A-11D-A00X-01): tumor purity 0.68, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:47,045,538–47,176,511, 2 genes, copy number 6 (within-gene range 2–6): STPG4, AC073283.3.
- chr2:47,160,083–47,663,146, 11 genes, copy number 6 (within-gene range 2–6): CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1.
- chr3:168,249,522–168,830,599, 1 gene, copy number 6 (within-gene range 2–8): EGFEM1P.
- chr3:168,551,854–169,663,775, 10 genes, copy number 5–8 (within-gene range 2–8): MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1.
- chr20:11,800,463–11,878,429, 1 gene, copy number 6 (within-gene range 1–6): LINC00687.
- chr20:11,838,355–12,381,255, 6 genes, copy number 6: AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.

Autosomal genes at a single copy (total copy number 1): 21,203. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
